Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5854, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5854-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Taken:
Received:
Reported:

=====

CLINICAL HISTORY

lower
extremities weakness, and more . On
imaging,
there is a 2.3 cm patchy, irregularly enhancing lesion involving the
white
matter at the level of the atrium and posterior body of the lateral
ventricle,
and extending to the right paramedian parietal lobe. The lesion has
been
enlarging recently.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain, right parietal lesion, biopsy
B: Brain, right parietal lesion, biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right parietal, excisional biopsies:

1. Astrocytoma, anaplastic (WHO III).
2. MIB-1 proliferation index: > 10%.
- See Microscopy Description and Comment.

COMMENT

The specimens are cerebral cortex and adjacent white matter in which
there is
extensive cautery artefact. The brain tissues are diffusely and
sparsely to
moderately infiltrated by an astrocytic neoplastic proliferation.
There are
no nuclear anaplastic features. There are a handful of mitotic
figures and
the MIB-1 proliferation index is higher than 10%. There is no
microvascular
cellular proliferation or tumor necrosis.

[page 2 of 4]
The neoplasm is an astrocytoma that infiltrates diffusely the brain parenchyma and has mitotic figures, in the absence of microvascular cellular proliferation or tumor necrosis, i.e. an anaplastic astrocytoma.

Electronically Signed Out

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay [REDACTED]
Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Allelic loss and chromosome arm 19q is detected.

There is partial deletion on chromosome arm 1p as evidenced by LOH at only
D1S496 locus

Informative loci are: D1S548, D1S552, D1S496, D19S219, D19S412, and PLA2G4C

Results-Comments

Test performed on DNA extracted from tumor paraffin block and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as

[page 3 of 4]
required by [REDACTED]. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A.

Brain, right parietal lesion, biopsy:

1. Touch prep and smears: Gliofibrillary proliferation ([REDACTED] glioma).

[REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record.

2. Frozen sections: Neoplastic astrocytic proliferation, [REDACTED] astrocytoma.

[REDACTED] Frozen section performed at [REDACTED] and results reported to the Physician of Record.

[REDACTED]

GROSS DESCRIPTION

A.

Brain, right parietal lesion, biopsy: Received fresh, three fragments.

Semi-firm, greyish-white. In total, A1 and A2; frozen tissue A3.

B.

Brain, right parietal lesion, biopsy:

CONTAINER LABEL: right parietal lesion permanent

FIXATIVE: fresh

GENERAL: received are few pink-tan fragments of tissue, aggregating to 1.8 x

1.2 x 0.3 cm.

SECTIONS: 1, NS

Mid 2143

[REDACTED]

[page 4 of 4]
MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a moderately fibrillary background. The EMA has a diffuse, tenuous background positive reaction, probably artefactual. The CD163 depicts moderately activated, mostly perivascular microglia. A majority of neoplastic astrocytes over express the p53 protein. With the MIB-1 there is a proliferation index of about 10% (including non-neoplastic nuclei).

Histo Data

Part A: Brain, right parietal lesion, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
FS H/E x 1		1		
H/E x 1		1		
[redacted] E x 1		1		
[redacted] x 1		2		
mGFAP-DA x 1				
H/E x 1				
MIB1-DA x 1				
P53DO7 x 1				
H/E x 1				
CD163 Vector				

Part B: Brain, right parietal lesion, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		

*** End of Report ***

Source: NCI Genomic Data Commons file 07c14d5a-47d1-4616-b7ac-e1ef0dde6c96 (TCGA-DU-5854.E057679F-9741-4A4E-BB60-E03879B1C723.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).